Somatic mutation profile of tumor specimen TCGA-BR-4255-01A (aliquot TCGA-BR-4255-01A-01D-1126-08) from TCGA case TCGA-BR-4255, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,893 days).
Specimen TCGA-BR-4255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49fc013c-7766-4065-b575-e4e88ce4450f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4255-11A (Solid Tissue Normal), aliquot TCGA-BR-4255-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e52ba1b0-d49d-4437-bd34-b11a1686993e

The open-access MAF lists 59 somatic variants for this specimen: 41 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 29, Silent 18, Nonsense Mutation 7, Frame Shift Del 3, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV54440376; called by muse, mutect2, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV67977934; called by muse, mutect2, varscan2
- AL031777.2 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs140533379; called by mutect2, varscan2
- BRF2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV55103034; called by muse, mutect2
- BUD31 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52861871; called by muse, mutect2
- CCDC80 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759648511, COSV52815608; called by muse, mutect2, varscan2
- CDYL | c.244C>T p.R82W (on ENST00000328908 / NM_001368125.1; = p.R28W on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59358793; called by muse, mutect2, varscan2
- CSN1S1 | c.453C>G p.Y151* | Nonsense Mutation (SNP) | VAF 16/350 reads (5%) | catalogued as COSV55890036; called by muse, mutect2
- DCAF12 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768755671, COSV63511862; called by muse, mutect2, varscan2
- DCAF13 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.094); catalogued as COSV52570968, COSV52572292; called by muse, mutect2
- GRID1 | c.2080A>G p.K694E | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60018998; called by muse, mutect2, varscan2
- HPSE2 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65183770; called by muse, mutect2
- L3MBTL1 | c.2378G>A p.R793H (on ENST00000418998 / NM_001377303.1; = p.R703H on NM_015478.7) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs757597984, COSV64228087; called by muse, mutect2, varscan2
- MTF2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64769914; called by muse, mutect2, varscan2
- NEIL2 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 27/327 reads (8%) | catalogued as COSV52706427; called by muse, mutect2
- NPIPB15 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as rs1286631346, COSV101466019; called by muse, mutect2
- NPY | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54214776; called by muse, mutect2, varscan2
- NUTM1 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59216114; called by muse, mutect2, varscan2
- OTUD7B | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782789210, COSV64915565; called by muse, mutect2, varscan2
- PIGZ | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs200943195, COSV53013266; called by mutect2, varscan2
- PLS1 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs567963239, COSV61833143; called by muse, mutect2, varscan2
- PLXNA3 | c.5009A>C p.D1670A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63753513; called by muse, mutect2
- PMS1 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772427166, COSV59715315; called by muse, mutect2, varscan2
- POTEE | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); catalogued as rs370032960; called by muse, varscan2
- PPP2R2D | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV70778712; called by muse, mutect2, varscan2
- PYGB | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53816635; called by muse, mutect2, varscan2
- RBM28 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.635); catalogued as COSV56162088; called by muse, mutect2, varscan2
- SHANK2 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99575247; called by muse, mutect2, varscan2
- SIGLEC7 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs140841032, COSV58317452; called by muse, mutect2, varscan2
- TEK | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV66227903; called by muse, mutect2
- TIGD2 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs745978476, COSV57647408; called by muse, mutect2, varscan2
- TM4SF5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs768321534, COSV54496113; called by muse, mutect2, varscan2
- TPBG | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1301303146, COSV63882412; called by muse, mutect2
- TSGA10 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV61821928; called by muse, mutect2, varscan2
- WNT2B | c.406A>G p.S136G (on ENST00000369684 / NM_024494.3; = p.S117G on NM_004185.4) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV56673064; called by muse, mutect2, varscan2
- DOK5 | c.169_171del p.H57del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- NFKBIZ | c.989del p.P330Qfs*11 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | called by mutect2, pindel, varscan2
- PRRX1 | c.372del p.E125Kfs*7 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- ROCK1 | c.3827_3830del p.K1276Rfs*3 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by pindel, varscan2
- BTBD16 | c.984T>C p.R328= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV53261559; called by muse, mutect2
- CD44 | c.1974G>A p.L658= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as rs1428422221, COSV53528522; called by muse, mutect2
- CD96 | c.294G>A p.G98= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV51913961; called by muse, mutect2
- CNNM2 | c.1596C>T p.D532= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as COSV63995670; called by muse, mutect2, varscan2
- ETF1 | c.1290A>G p.E430= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV62127026; called by muse, mutect2
- IFNB1 | c.189G>A p.E63= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV66525208; called by muse, varscan2
- ITGA4 | c.1410C>T p.D470= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs183217259, COSV51997793; called by muse, mutect2, varscan2
- LRP1B | c.3126T>C p.C1042= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV67198201; called by muse, mutect2, varscan2
- PIAS3 | c.1483C>T p.L495= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV57906916; called by muse, mutect2
- RBM33 | c.2145G>A p.P715= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs780253723, COSV56630213; called by muse, mutect2, varscan2
- SBF1 | c.4797G>A p.A1599= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs771134293, COSV62366347; called by muse, mutect2, varscan2
- SCFD1 | c.1827C>T p.D609= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV61723000; called by muse, mutect2, varscan2
- SCN9A | c.2586A>T p.S862= (on ENST00000303354; = p.S851= on NM_002977.3) | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as COSV57603901; called by muse, mutect2, varscan2
- SLK | c.247T>C p.L83= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV59824411; called by muse, mutect2, varscan2
- STK10 | c.960C>T p.D320= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs139075094; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2343A>T p.T781= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV59127799; called by muse, mutect2, varscan2
- VWF | c.5532C>T p.G1844= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs754986617, COSV54612857; called by muse, mutect2, varscan2
- ZNF704 | c.1197C>T p.T399= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1043372993, COSV59921184; called by muse, mutect2
